Somatic mutation profile of tumor specimen TCGA-G5-6233-01A (aliquot TCGA-G5-6233-01A-11D-1733-10) from TCGA case TCGA-G5-6233, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 74.4 years (27,190 days).
Specimen TCGA-G5-6233-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bce1d460-15a0-43d1-99eb-29d92d790c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G5-6233-10A (Blood Derived Normal), aliquot TCGA-G5-6233-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fca26ed7-6426-4436-ae16-ba2c2414ee4c

The open-access MAF lists 176 somatic variants for this specimen: 139 protein-altering or splice-affecting, 37 silent.
By variant classification: Missense Mutation 119, Silent 37, Frame Shift Ins 5, Nonsense Mutation 5, Frame Shift Del 5, Splice Region 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 38/71 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 43/108 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LRP5 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121908671, CM030683, COSV53715230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM20 | c.1252G>C p.G418R | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56455121; called by muse, mutect2, varscan2
- ADAMTS18 | c.623A>T p.E208V | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV51413644; called by muse, mutect2, varscan2
- ADGRA2 | c.336del p.K112Nfs*4 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | catalogued as COSV59443919; called by mutect2, pindel, varscan2
- ADORA1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100526731, COSV58810693; called by muse, mutect2, varscan2
- AHNAK | c.6764G>T p.G2255V | Missense Mutation (SNP) | VAF 101/153 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57215307; called by muse, mutect2, varscan2
- BIRC6 | c.13829A>C p.K4610T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70199830; called by muse, mutect2, varscan2
- BMPR1A | c.1078C>G p.H360D | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64406327; called by muse, mutect2, varscan2
- BRD1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1281211435, COSV53457814; called by muse, mutect2, varscan2
- C11orf42 | c.672C>G p.N224K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56411755; called by muse, mutect2, varscan2
- C5orf34 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547063153, COSV100175534, COSV60930365; called by muse, mutect2, varscan2
- CCDC102B | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.146); catalogued as COSV60143355; called by muse, mutect2, varscan2
- CCDC191 | c.2521A>T p.I841F | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.49); catalogued as COSV55672619; called by muse, mutect2, varscan2
- CENPJ | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 206/330 reads (62%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV67883148; called by muse, mutect2, varscan2
- CHST9 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs768328169, COSV52438373, COSV99411043; called by muse, mutect2, varscan2
- CNTN1 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767168253, COSV61640216; called by muse, mutect2, varscan2
- COL2A1 | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61531070; called by muse, mutect2, varscan2
- COPA | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV99614681; called by muse, mutect2, varscan2
- COPB2 | c.378G>C p.W126C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60812733; called by muse, mutect2, varscan2
- CRHBP | c.84G>A p.L28= | Splice Region (SNP) | VAF 31/67 reads (46%) | catalogued as COSV57188671; called by muse, mutect2, varscan2
- CTNNAL1 | c.245T>G p.F82C | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57703135; called by muse, mutect2, varscan2
- DCPS | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55011073; called by muse, mutect2, varscan2
- DGKH | c.2494-1G>A p.X832_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99818361; called by mutect2, varscan2
- DNAAF2 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1224853450, COSV53569739; called by muse, mutect2, varscan2
- DST | c.16356C>G p.I5452M (on ENST00000361203 / NM_001374722.1; = p.I3040M on NM_015548.5) | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV55017453; called by muse, mutect2
- DST | c.11615A>T p.Q3872L (on ENST00000361203 / NM_001374722.1; = p.Q1460L on NM_015548.5) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166257110, COSV55017470; called by muse, mutect2, varscan2
- DYNC2H1 | c.4845A>C p.Q1615H | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62095295; called by muse, mutect2, varscan2
- EMC9 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); catalogued as COSV52824306; called by muse, mutect2, varscan2
- ENPP6 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.184); catalogued as rs543843235, COSV57066923; called by muse, mutect2, varscan2
- EPHA5 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs770587480, COSV56633488; called by muse, mutect2, varscan2
- EPS8L1 | c.1163C>A p.P388Q (on ENST00000201647 / NM_133180.3; = p.P261Q on NM_017729.3) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV52380569, COSV99135671; called by muse, mutect2, varscan2
- ESRP2 | c.1816C>A p.P606T (on ENST00000565858 / NM_001365264.1; = p.P596T on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV52173758; called by muse, mutect2, varscan2
- FAM47B | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs778311712, COSV61454246; called by muse, mutect2, varscan2
- FAT4 | c.2681T>G p.L894R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.61); catalogued as COSV67887995; called by muse, mutect2, varscan2
- FCRLA | c.164C>T p.T55M (on ENST00000367959; = p.T32M on NM_032738.4) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs753826864, COSV52686120; called by muse, mutect2, varscan2
- FHDC1 | c.469A>G p.N157D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV52600304; called by muse, mutect2, varscan2
- FLNC | c.6878G>A p.R2293H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs1034483511, COSV57956670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FN1 | c.7133A>G p.Q2378R (on ENST00000359671 / NM_001365524.2; = p.Q2347R on NM_002026.4) | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.956); catalogued as COSV60554143; called by muse, mutect2, varscan2
- FXR1 | c.1666G>T p.E556* | Nonsense Mutation (SNP) | VAF 147/583 reads (25%) | catalogued as COSV59763368; called by muse, mutect2, varscan2
- GRIA3 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs746222344, COSV52062280, COSV52081678; called by muse, mutect2, varscan2
- HOXA6 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761372561, COSV56074046; called by mutect2, varscan2
- HOXC10 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57726367; called by muse, mutect2, varscan2
- HRH2 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV51574474; called by muse, mutect2, varscan2
- IGSF1 | c.1706T>G p.L569R | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1277147662, COSV63837804; called by muse, mutect2, varscan2
- IL26 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV57489109; called by muse, mutect2, varscan2
- IRX2 | c.1151A>T p.Y384F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100121580; called by muse, mutect2, varscan2
- ITGA5 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53216385, COSV53218024; called by muse, mutect2, varscan2
- KCNA4 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.102); catalogued as rs764565549, COSV100069216, COSV60252671; called by muse, mutect2, varscan2
- KCNJ8 | c.960G>T p.W320C | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53716616, COSV53716832; called by muse, mutect2, varscan2
- KLHL23 | c.1651G>T p.G551W | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.89); catalogued as COSV55867416; called by muse, mutect2, varscan2
- L1TD1 | c.2047C>G p.Q683E | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.099); catalogued as COSV63133544; called by muse, mutect2, varscan2
- LAMB1 | c.3487G>T p.D1163Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99739964; called by muse, mutect2, varscan2
- LDHB | c.832delinsTT p.V278Ffs*8 | Frame Shift Ins (INS) | VAF 13/122 reads (11%) | catalogued as COSV63364808; called by mutect2*, pindel, varscan2*
- LIFR | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.369); catalogued as COSV54691126; called by muse, mutect2, varscan2
- LRP12 | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs761326626, COSV99407241; called by muse, mutect2, varscan2
- LRRC37A3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs150916228; called by muse, mutect2, varscan2
- LTBP4 | c.1783C>G p.P595A (on ENST00000308370 / NM_001042544.1; = p.P558A on NM_003573.2) | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV99180519; called by muse, mutect2, varscan2
- MAPKBP1 | c.4366C>A p.L1456I (on ENST00000456763 / NM_001128608.2; = p.L1450I on NM_014994.3) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.293); catalogued as COSV99528956; called by muse, mutect2, varscan2
- MARS1 | c.2590G>T p.A864S | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV56255223; called by muse, mutect2, varscan2
- MON2 | c.3396G>T p.L1132F | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV99741675; called by muse, mutect2
- MPEG1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99915042; called by muse, mutect2
- MPZ | c.435T>A p.Y145* | Nonsense Mutation (SNP) | VAF 20/191 reads (10%) | catalogued as CM082950, COSV60668411; called by muse, mutect2
- MYO7A | c.3752C>T p.A1251V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68684897; called by muse, mutect2, varscan2
- NBEA | c.3445G>C p.D1149H | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); catalogued as COSV59788487; called by muse, mutect2, varscan2
- NOC2L | c.99A>C p.E33D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV58532047; called by muse, mutect2, varscan2
- NOP2 | c.1330G>A p.G444R (on ENST00000322166 / NM_001258308.2; = p.G440R on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59110848; called by muse, mutect2, varscan2
- NRK | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 116/171 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs773413744, COSV54597835; called by muse, mutect2, varscan2
- OFD1 | c.2456A>T p.K819M | Missense Mutation (SNP) | VAF 203/288 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV60796197; called by muse, mutect2, varscan2
- P2RX5 | c.531G>A p.P177= | Splice Region (SNP) | VAF 21/45 reads (47%) | catalogued as rs371399618, COSV56590815; called by muse, mutect2, varscan2
- PALD1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs148960582; called by muse, mutect2, varscan2
- PC | c.2435C>A p.A812D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58992904; called by muse, mutect2, varscan2
- PCDH15 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57319974; called by muse, mutect2, varscan2
- PCDHA13 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.017); catalogued as rs1554176457, COSV56506842; called by muse, mutect2, varscan2
- PCDHA13 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV56506855; called by muse, mutect2, varscan2
- PCLO | c.1343_1347del p.K448Tfs*96 | Frame Shift Del (DEL) | VAF 54/137 reads (39%) | catalogued as COSV61638580; called by mutect2, pindel, varscan2
- PCSK2 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs528344186, COSV52733708; called by muse, mutect2, varscan2
- PDZRN4 | c.2267C>G p.P756R (on ENST00000402685 / NM_001164595.2; = p.P498R on NM_013377.4) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54203215; called by muse, mutect2, varscan2
- PHF13 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV50010972, COSV50011407; called by muse, mutect2, varscan2
- PIK3C2G | c.2516del p.N839Mfs*16 (on ENST00000676171; = p.N798Mfs*16 on NM_004570.5) | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | catalogued as rs1229278001; called by mutect2, pindel*
- PIP5K1B | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as rs145998457, COSV55255994; called by muse, mutect2, varscan2
- PITRM1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV56532391; called by muse, mutect2, varscan2
- PLA2G2F | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV64280042; called by muse, mutect2, varscan2
- PLPP2 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54120833; called by muse, mutect2, varscan2
- PLXNA3 | c.4190G>T p.S1397I | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV63754243; called by muse, mutect2, varscan2
- PMS2 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56221902, COSV56222346; called by muse, mutect2, varscan2
- POM121L12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692577; called by muse, mutect2
- PRDM5 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53361323; called by muse, mutect2, varscan2
- PRRG1 | c.515A>T p.Y172F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66157737; called by muse, mutect2, varscan2
- RBM44 | c.1125A>T p.E375D (on ENST00000611254; = p.E1009D on NM_001080504.2) | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV57629939; called by muse, mutect2, varscan2
- RHBDD3 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99328422; called by muse, mutect2, varscan2
- ROCK1 | c.326A>T p.K109I | Missense Mutation (SNP) | VAF 76/128 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67696319; called by muse, mutect2, varscan2
- ROCK2 | c.4027C>T p.R1343W | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59957891; called by muse, mutect2, varscan2
- RPAP3 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 226/639 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs997144280, COSV50041865; called by muse, mutect2, varscan2
- RPS2 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as rs76844476, COSV51910109; called by muse, mutect2, varscan2
- RXRG | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV63232227; called by muse, mutect2, varscan2
- SCAPER | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 164/273 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.674); catalogued as rs1261962491, COSV57741471; called by muse, mutect2, varscan2
- SFXN3 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as rs1010386584, COSV99827361; called by muse, mutect2, varscan2
- SLC35F5 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV55518594; called by muse, mutect2, varscan2
- SLIT2 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.806); catalogued as rs1257940389, COSV56565535; called by muse, mutect2, varscan2
- SLIT3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766150043, COSV60595120; called by muse, mutect2, varscan2
- SLITRK1 | c.1524C>A p.Y508* | Nonsense Mutation (SNP) | VAF 8/127 reads (6%) | catalogued as COSV100999793; called by muse, mutect2
- SNRK | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV56068319; called by muse, mutect2, varscan2
- SPAG16 | c.1687A>G p.S563G | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs1278165214, COSV100530109, COSV100536780; called by muse, varscan2
- ST3GAL6 | c.738A>T p.K246N | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV54580153, COSV54581667; called by muse, mutect2, varscan2
- ST7 | c.301T>G p.L101V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55385774; called by muse, mutect2, varscan2
- SULT1B1 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60207830; called by muse, mutect2, varscan2
- SYNE1 | c.5205G>C p.M1735I (on ENST00000367255 / NM_182961.4; = p.M1742I on NM_033071.3) | Missense Mutation (SNP) | VAF 115/212 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54995903; called by muse, mutect2, varscan2
- TALDO1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs778205812, COSV59797652; called by muse, mutect2, varscan2
- TBC1D7 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.945); catalogued as rs766235427, COSV58243933; called by muse, mutect2, varscan2
- TG | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs762257905, COSV55078330; called by mutect2, varscan2
- TP53 | c.369_370dup p.C124Ffs*47 | Frame Shift Ins (INS) | VAF 37/75 reads (49%) | catalogued as COSV52717910, COSV53118583; called by mutect2, pindel, varscan2
- TRAPPC11 | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.239); catalogued as COSV58216803; called by muse, mutect2, varscan2
- TRIM48 | c.204C>A p.C68* | Nonsense Mutation (SNP) | VAF 160/1762 reads (9%) | catalogued as COSV101338197; called by muse, mutect2
- TRPS1 | c.3748C>T p.H1250Y (on ENST00000220888 / NM_001330599.2; = p.H1263Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/444 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55242537, COSV99628582; called by muse, mutect2, varscan2
- TTN | c.89513A>G p.Y29838C (on ENST00000591111; = p.Y22414C on NM_003319.4) | Missense Mutation (SNP) | VAF 55/176 reads (31%) | PolyPhen probably damaging (0.999); catalogued as rs879013044, COSV60097592; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.12034A>G p.R4012G (on ENST00000591111; = p.R3966G on NM_003319.4) | Missense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV60097699; called by muse, mutect2
- USP43 | c.2763G>C p.Q921H | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV53303108; called by muse, mutect2, varscan2
- WNK1 | c.5362C>G p.Q1788E (on ENST00000315939 / NM_018979.4; = p.Q1541E on NM_014823.3) | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60034634; called by muse, mutect2
- WNK3 | c.5317G>C p.G1773R | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as COSV63612875, COSV63614331; called by muse, mutect2, varscan2
- ZFP64 | c.699C>A p.C233* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV53799795; called by muse, mutect2
- ZNF506 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71354410; called by muse, mutect2, varscan2
- ZNF540 | c.673A>G p.S225G | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100329458; called by muse, mutect2
- ZNF587 | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV57148724; called by muse, mutect2, varscan2
- ZNF836 | c.2531T>C p.I844T | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs373736034; called by muse, mutect2, varscan2
- ZSCAN20 | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63682914; called by muse, mutect2, varscan2
- COL6A1 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.191); called by muse, varscan2
- DPYSL2 | c.219_239del p.T74_D80del | In Frame Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, pindel
- FOXR1 | c.463dup p.L155Pfs*78 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by pindel, varscan2
- IGHV3-20 | c.149A>C p.D50A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LGALS3BP | c.1318dup p.V440Gfs*6 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by pindel, varscan2
- MEX3A | c.1362dup p.L455Tfs*20 | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by pindel, varscan2
- NOS1 | c.2583del p.K861Nfs*22 | Frame Shift Del (DEL) | VAF 49/97 reads (51%) | called by mutect2, pindel, varscan2
- PCDH15 | c.5682del p.K1894Nfs*3 | Frame Shift Del (DEL) | VAF 64/307 reads (21%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1053_1058del p.G352_Y353del | In Frame Del (DEL) | VAF 64/155 reads (41%) | called by mutect2, pindel, varscan2
- SOX21 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.014); called by muse, mutect2
- VWF | c.5491T>C p.Y1831H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRV1 | c.1497C>T p.S499= | Silent (SNP) | VAF 69/130 reads (53%) | catalogued as rs201377512, COSV67986307; called by muse, mutect2, varscan2
- ANK2 | c.3975T>C p.P1325= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV52163719; called by muse, mutect2, varscan2
- ANKRD52 | c.1785C>T p.N595= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs770340773, COSV99921050; called by muse, mutect2, varscan2
- ASPHD1 | c.771A>T p.A257= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV58099801; called by muse, mutect2, varscan2
- CDH9 | c.264A>G p.L88= | Silent (SNP) | VAF 19/199 reads (10%) | catalogued as COSV99141827; called by muse, mutect2
- CFLAR | c.123G>C p.L41= | Silent (SNP) | VAF 94/317 reads (30%) | catalogued as COSV57937181; called by muse, mutect2, varscan2
- CFP | c.747C>T p.T249= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1301892513, COSV55949836; called by muse, mutect2, varscan2
- CHRFAM7A | c.690C>T p.H230= | Silent (SNP) | VAF 195/705 reads (28%) | catalogued as rs371263130; called by muse, mutect2, varscan2
- DIP2A | c.3573C>T p.I1191= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs745968215, COSV59478435; called by muse, mutect2, varscan2
- FIGNL1 | c.681A>G p.E227= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV63553553; called by muse, mutect2, varscan2
- INHA | c.174G>A p.L58= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV54720412, COSV54723621; called by muse, mutect2, varscan2
- INPP5J | c.2265G>A p.A755= (on ENST00000331075 / NM_001284285.2; = p.A387= on NM_001002837.2) | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs544342010, COSV99311336; called by muse, mutect2, varscan2
- IPO13 | c.1683C>T p.D561= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV64894424; called by muse, mutect2, varscan2
- KRT33A | c.630C>T p.N210= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as rs145206731; called by mutect2, varscan2
- LGALS3BP | c.1326T>C p.Y442= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1482974492, COSV53165092; called by muse, varscan2
- LRTM2 | c.459C>T p.A153= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV54565234; called by muse, mutect2, varscan2
- MAGEL2 | c.1995C>T p.P665= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as rs567654551, COSV58567458; called by muse, mutect2, varscan2
- NRXN1 | c.3864C>T p.I1288= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as rs201464255, COSV60500950; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5D18 | c.894C>A p.V298= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs778491754, COSV61737268; called by muse, mutect2, varscan2
- PRDM16 | c.1080C>T p.H360= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs761160322, COSV54592581; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRRC2B | c.303G>A p.A101= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1264402181, COSV61937629; called by muse, mutect2, varscan2
- PTPN4 | c.1158A>G p.Q386= | Silent (SNP) | VAF 65/182 reads (36%) | catalogued as COSV55302127; called by muse, mutect2, varscan2
- RAPH1 | c.1248T>C p.R416= (on ENST00000319170 / NM_213589.3; = p.R468= on NM_203365.4) | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as COSV100051126; called by muse, mutect2, varscan2
- RNF186 | c.273C>A p.V91= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs771689670, COSV100909080; called by muse, mutect2, varscan2
- SACS | c.13354A>C p.R4452= | Silent (SNP) | VAF 68/304 reads (22%) | catalogued as COSV66540666; called by muse, mutect2, varscan2
- SDCBP2 | c.273C>T p.T91= (on ENST00000339987 / NM_001199784.1; = p.T6= on NM_015685.5) | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV60589545; called by muse, mutect2, varscan2
- SGCG | c.642C>T p.H214= | Silent (SNP) | VAF 107/191 reads (56%) | catalogued as rs528994151, COSV54561453; called by muse, mutect2, varscan2
- SLC2A8 | c.1269C>T p.L423= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs34424745, COSV100972664; called by muse, mutect2, varscan2
- SOCS5 | c.345T>C p.S115= | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as COSV100125006; called by muse, mutect2, varscan2
- SOX2 | c.912C>A p.P304= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100327088; called by muse, mutect2, varscan2
- STIM1 | c.636G>A p.K212= | Silent (SNP) | VAF 69/398 reads (17%) | catalogued as rs201872975, COSV100330532; called by muse, mutect2, varscan2
- TACC2 | c.8469C>T p.A2823= (on ENST00000334433; = p.A901= on NM_006997.4) | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs545114672, COSV53282063; called by muse, mutect2, varscan2
- TIE1 | c.1758C>T p.D586= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs201759080; called by muse, mutect2, varscan2
- TMEM266 | c.522C>T p.D174= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs376311119; called by muse, mutect2, varscan2
- TTC21A | c.3363C>A p.S1121= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV56188211, COSV99826856; called by muse, mutect2, varscan2
- TTN | c.89511A>G p.E29837= (on ENST00000591111; = p.E22413= on NM_003319.4) | Silent (SNP) | VAF 54/177 reads (31%) | catalogued as COSV60097641; called by muse, mutect2
- UNC13A | c.2328C>T p.S776= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs566710071, COSV53188360, COSV53197127; called by muse, mutect2, varscan2
